Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54J, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54J-01A (Primary Tumor).

[page 1 of 4]
ICD-6-3
Carcinoma, renal cell, NOS
Clear Cell type 831213
Site: (R) Kidney C64.9
11/30/12 ^{NOS} 41

Diagnosis:

A: Kidney, right, nephrectomy

Tumor histologic type: renal cell carcinoma, clear cell subtype

Sarcomatoid features: not identified

Histologic grade: 2 (of 4, Fuhrman classification)

Tumor size: 8.6 cm

Tumor focality: unifocal

Extent of invasion:

Extra-capsular invasion into perirenal adipose tissue: not identified

Gerota' s fascia: present, not involved

Renal sinus: not involved

Major veins (renal vein or segmental branches, IVC): not involved

Ureter: not involved

Venous: not identified

Lymphatic: not identified

Surgical margins:

Perinephric adipose tissue margin: not involved

Renal vein: not involved

Ureter: not involved

Adrenal gland: not present for evaluation

Lymph nodes: none present for evaluation

Pathologic findings in non-neoplastic kidney:

arteriolonephrosclerosis,

focal simple cyst, focal adenoma, variable interstitial chronic inflammation

AJCC Stage: pT2a pNx pMx

This staging information is based on information available at the time of this

[page 2 of 4]
report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old male with a right renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: right nephrectomy

Side of specimen: right

Size and weight of specimen: 1,274 grams; 24.5 x 14.5 x 9.5 cm

Orientation: The margins are inked blue

Presence/absence of adrenal gland: absent

Tumor site: The tumor involves the renal cortex and medulla of the lower pole.

Tumor description: The tumor is heterogeneous and consists of solid and cystic areas (primarily solid) with foci of hemorrhage and interspersed yellow/orange and brown areas of necrosis.
The tumor is well circumscribed.

Tumor size: From inferior to superior pole is 8.6 cm, from medial to lateral is 8.3 cm, the anterior/posterior is 6.2 cm.

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined, abutting the renal capsule

Extent of invasion:

[page 3 of 4]
Perirenal adipose tissue: tumor does not involve

Gerota' s fascia: tumor does not involve

Renal vein: does not involve

Ureter: does not involve

Renal Sinus: does not involve

Pelvicaliceal: does not involve

Adrenal: does not involve

Other organs: does not involve

Surgical margins:

Perirenal adipose tissue: negative; The tumor pushes the renal capsule and is 1 mm from the perirenal adipose tissue and 1.0 cm from the blue inked edge of the perirenal adipose tissue margin.

Renal vein: negative; The tumor is 2.5 cm from the margin.

Renal artery: negative; The tumor is 2.8 cm from the margin.

Ureter: negative; The mass is 1.5 cm from the ureter margin.

Description of kidney away from tumor: The remaining renal parenchyma is compressed with multiple cysts (the largest has a greatest diameter of 3.1 cm).

Hilar lymph nodes: none identified

Other significant findings: none

Tissue submitted for special investigations: yes; Tumor and normal tissue were submitted to Tissue Procurement.

Digital picture: not taken

Block summary:

A1 - ureter, vein, artery margins, en face

[page 4 of 4]
A2 - representative section of tumor in relation to normal
parenchyma
A3 - representative sections of tumor in relation to the renal
sinus
A4 - tumor bulging renal capsule
A5 - tumor in relation to closest inked margin
A6 - renal cyst
A7 - representative section of uninvolved renal tissue
A8 - representative section of tumor
A9-A12 - representative sections of perihilar fat
Tissue remains in the container.

10/21/12

Reviewed:	11/20/12	

KMI

Source: NCI Genomic Data Commons file 1911fe44-f6b6-4ea0-8c62-287b3f5738ee (TCGA-B8-A54J.C05E0ED7-C05B-4118-AFBA-75AE969464FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).